Surgical pathology report (de-identified scan), TCGA case TCGA-BF-A3DL, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Cureline, specimen TCGA-BF-A3DL-01A (Primary Tumor).

Case #: DOB: Sex: Female Ethnicity (Race):

Cancer Sample

Diagnosis: Melanoma Histological description: Melanoma

Date of Procurement: Anatomic Site: Skin Tumor location: Primary

Tissue Specification: Tumor Specimen Matrix: Tissue Specimen Format: Frozen

Container: cryomold Type of Procurement: Surgery Grade: 2

T Stage: 4 N Stage: 2 M Stage: 0 Treatment: no

Treatment Details: no/no

ICD-0-3
Melanoma, NOS 8720/3
Site: Skin, NOS C44.9

Normal Sample

Anatomic Site: Blood Sample Type: normal Type of Procurement: Blood draw

Matrix: Blood Specimen Format: Frozen Container: tube

Date of Procurement:

hw
10/15/11

Tumor Malignancy History		

Source: NCI Genomic Data Commons file aa25d84b-ae4f-4895-ae17-1784577761ca (TCGA-BF-A3DL.EDB2BE60-AB50-4C1D-8B73-410E8B4A9AED.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).